TCGA case TCGA-G4-6310 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/14c13b05-abfe-472e-83a9-b28f60e58ad8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 69 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.9; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Cecum; Classification of tumor: primary; Age at diagnosis: 69.1 years (25,243 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Prior malignancy: yes; Synchronous malignancy: Yes; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,935 days (5.3 years).
   Pathology details: Circumferential resection margin: 8; Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 66; Lymphatic invasion present: No; Non nodal tumor deposits: No; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 34 days; Days to treatment end: 76 days; Number of cycles: 4.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Treatment intent type: Adjuvant; Days to treatment start: 34 days; Days to treatment end: 76 days; Number of cycles: 4; Treatment dose: 3,200 mg; Prescribed dose: 840; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Adjuvant; Days to treatment start: 34 days; Days to treatment end: 76 days; Number of cycles: 4; Treatment dose: 684 mg; Prescribed dose: 180; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Treatment intent type: Adjuvant; Days to treatment start: 90 days; Days to treatment end: 132 days; Treatment dose: 90,000 mg; Prescribed dose: 3000; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 90 days; Days to treatment end: 132 days; Treatment dose: 5,400 cGy; Course number: 1; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 153 days; Days to treatment end: 194 days; Number of cycles: 4.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Treatment intent type: Adjuvant; Days to treatment start: 153 days; Days to treatment end: 194 days; Number of cycles: 4; Treatment dose: 3,200 mg; Prescribed dose: 800; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Adjuvant; Days to treatment start: 153 days; Days to treatment end: 194 days; Number of cycles: 4; Treatment dose: 680 mg; Prescribed dose: 170; Prescribed dose units: mg; Route of administration: Intravenous.
2. Prior malignancy (histology not recorded by GDC).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment anatomic sites: Body, total.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 1,205 days (3.3 years); Disease response: Tumor Free.
- Days to follow up: 1,372 days (3.8 years); Disease response: Tumor Free.
- Days to follow up: 1,935 days (5.3 years); Disease response: Tumor Free.

Molecular and laboratory tests
- MLH1 (IHC): Normal.
- MSH2 (IHC): Normal.
- MSH6 (IHC): Normal.
- PMS2 (IHC): Normal.
- Microsatellite Instability: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 102.5 kg; Height: 173 cm; BMI: 34.2.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-G4-6310-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.6; Intermediate dimension: 1; Shortest dimension: 0.3.
  Slide TCGA-G4-6310-01A-01-BS1: Section location: Bottom; Percent tumor cells: 79; Percent tumor nuclei: 85; Percent normal cells: 1; Percent necrosis: 10; Percent stromal cells: 10.
  Slide TCGA-G4-6310-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 75; Percent normal cells: 12; Percent necrosis: 8; Percent stromal cells: 10.
- Sample TCGA-G4-6310-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-G4-6310-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Height cm at diagnosis: 173 cm; Anatomic organ subdivision: Cecum; Lymph nodes examined: Yes; Lymphovascular invasion indicator: No; Microsatellite instability: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: No; Mismatch rep proteins tested by IHC: Yes.
- Loss expression of mismatch repair proteins by ihc results: Mismatch rep proteins loss IHC: MLH1-Expressed; Mismatch rep proteins loss IHC: MSH2-Expressed; Mismatch rep proteins loss IHC: PMS2-Expressed; Mismatch rep proteins loss IHC: MSH6-Expressed.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: 5-FU.
- Drug treatment 2: Regimen number: 2; Pharmaceutical therapy drug name: Xeloda.
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Drug treatment 3: Regimen number: 3; Pharmaceutical therapy drug name: 5-FU.
- Drug treatment 4, Route of administrations: Route of administration: IV.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Lymphoma.
- Other malignancy form, Drug treatment: Pharmaceutical therapy extent: Systemic.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: Prior malignancy lymphoma treated with systemic chemotherapy.
- Prior malignancy: Prior malignancy lymphoma treated with systemic chemotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,935 days; disease-specific survival: no event (censored), 1,935 days; disease-free interval: no event (censored), 1,935 days; progression-free interval: no event (censored), 1,935 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-G4-6310-01): tumor purity 0.55, ploidy 3.54, whole-genome doublings 1 (call status: legacy_call).
